Somatic mutation profile of tumor specimen ALCH-AEO7-TTP1-A (aliquot ALCH-AEO7-TTP1-A-10-0-D-A612-36) from ALCHEMIST case ALCH-AEO7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 47.0 years (17,185 days).
Specimen ALCH-AEO7-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74294970-0f84-4a25-bb7b-7911db8b5fd5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEO7-NB1-A (Blood Derived Normal), aliquot ALCH-AEO7-NB1-A-1-0-D-A612-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e70a7a3-d42a-465d-9e09-dea19e72664b

The open-access MAF lists 345 somatic variants for this specimen: 248 protein-altering or splice-affecting, 59 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 215, Silent 59, Intron 13, RNA 9, Nonsense Mutation 9, 3'UTR 8, Splice Site 8, Frame Shift Del 8, 5'UTR 5, Frame Shift Ins 4, Splice Region 2, IGR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 20/152 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587781504, COSV52708806, COSV52766179, COSV52793434; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACE | c.3282-1G>T p.X1094_splice | Splice Site (SNP) | VAF 102/838 reads (12%) | catalogued as COSV52014678; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1798G>T p.G600C | Missense Mutation (SNP) | VAF 33/292 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs759212406; called by muse, mutect2, varscan2
- ALDH1L1 | c.769G>T p.E257* | Nonsense Mutation (SNP) | VAF 32/226 reads (14%) | catalogued as COSV56411050; called by muse, mutect2, varscan2
- AR | c.2729G>T p.G910V | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65953743, COSV65958355; called by muse, mutect2, varscan2
- ASTN2 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.236); catalogued as rs1410415075, COSV57767247; called by muse, mutect2, varscan2
- BCS1L | c.720-5C>T | Splice Region (SNP) | VAF 28/332 reads (8%) | catalogued as rs763546035; called by muse, mutect2
- BIRC6 | c.5422A>G p.T1808A | Missense Mutation (SNP) | VAF 92/676 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.155); catalogued as rs376251477; called by muse, mutect2, varscan2
- C17orf98 | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.704); catalogued as rs764504486; called by muse, mutect2, varscan2
- C2CD4B | c.580C>A p.R194S | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.066); catalogued as rs1243289558; called by muse, mutect2, varscan2
- CASR | c.2831C>A p.T944K (on ENST00000490131; = p.T1021K on NM_000388.4) | Missense Mutation (SNP) | VAF 60/419 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); catalogued as rs759009566; called by muse, mutect2, varscan2
- CCDC141 | c.2350G>T p.D784Y | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as COSV55373017; called by muse, mutect2
- CCDC148 | c.148-1G>C p.X50_splice | Splice Site (SNP) | VAF 25/238 reads (11%) | catalogued as COSV51755587; called by muse, mutect2, varscan2
- COL11A1 | c.3555G>T p.E1185D | Missense Mutation (SNP) | VAF 62/406 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.1); catalogued as COSV100615975; called by muse, mutect2, varscan2
- COL5A1 | c.2034+1G>T p.X678_splice | Splice Site (SNP) | VAF 29/175 reads (17%) | catalogued as COSV65670134; called by muse, mutect2, varscan2
- CTBP1 | c.1047C>G p.N349K | Missense Mutation (SNP) | VAF 30/217 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV52072299; called by muse, mutect2, varscan2
- CYP20A1 | c.760G>T p.D254Y | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100619121; called by muse, mutect2, varscan2
- DCAF12L2 | c.671C>A p.P224Q | Missense Mutation (SNP) | VAF 21/237 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.726); catalogued as COSV63582035; called by muse, mutect2
- DENND4B | c.3362T>A p.L1121H | Missense Mutation (SNP) | VAF 100/834 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as rs747460701; called by muse, mutect2, varscan2
- DNMT3B | c.1918G>T p.G640C | Missense Mutation (SNP) | VAF 56/418 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1310120, COSV52417563; called by muse, mutect2, varscan2
- DSCAML1 | c.3844C>A p.R1282S (on ENST00000321322; = p.R1222S on NM_020693.4) | Missense Mutation (SNP) | VAF 40/270 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.814); catalogued as COSV58385398; called by muse, mutect2, varscan2
- EIF2AK1 | c.1552G>T p.V518L | Missense Mutation (SNP) | VAF 54/378 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs777598704; called by muse, varscan2
- EIF4A2 | c.593A>G p.Y198C | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99961104; called by mutect2, varscan2
- EPHA6 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as rs572811264, COSV101060615, COSV67570244; called by muse, mutect2, varscan2
- EPHB6 | c.680G>T p.R227M | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV101235984; called by muse, mutect2, varscan2
- ERCC2 | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 46/349 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs772245022; called by muse, mutect2, varscan2
- FAM160A1 | c.2231C>T p.A744V | Missense Mutation (SNP) | VAF 50/228 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs961354256; called by muse, mutect2, varscan2
- FARP2 | c.1309G>A p.V437I | Missense Mutation (SNP) | VAF 67/504 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs754112585; called by muse, mutect2, varscan2
- FAT1 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV101499606; called by muse, mutect2, varscan2
- FAT3 | c.871G>T p.D291Y | Missense Mutation (SNP) | VAF 33/262 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53092933; called by muse, mutect2, varscan2
- FLG | c.3104C>T p.S1035F | Missense Mutation (SNP) | VAF 82/693 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100910478, COSV100911331; called by muse, mutect2, varscan2
- FLG | c.902G>T p.R301M | Missense Mutation (SNP) | VAF 88/889 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100910511; called by muse, mutect2
- GNPDA2 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.087); catalogued as rs974967723; called by muse, mutect2, varscan2
- GSTA2 | c.261G>T p.K87N | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72415113; called by muse, varscan2
- IL10RA | c.1027C>A p.Q343K | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.444); catalogued as rs530537648, COSV99923305; called by muse, mutect2, varscan2
- KIF18A | c.306G>C p.L102F | Missense Mutation (SNP) | VAF 41/350 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1201630561; called by muse, mutect2, varscan2
- KLHL13 | c.1429C>A p.P477T | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.771); catalogued as COSV53251791; called by muse, mutect2
- LRP1B | c.1636G>C p.D546H | Missense Mutation (SNP) | VAF 38/323 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV67265923; called by muse, mutect2, varscan2
- MAGEB18 | c.254C>A p.A85D | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as COSV57464528; called by muse, mutect2, varscan2
- MC5R | c.55G>T p.G19C | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV61254822; called by muse, mutect2
- MDN1 | c.2431G>A p.E811K | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV101021442; called by muse, mutect2, varscan2
- MKI67 | c.2578G>C p.D860H | Missense Mutation (SNP) | VAF 47/337 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.621); catalogued as COSV100896010; called by muse, mutect2, varscan2
- MMP26 | c.748C>G p.H250D | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV56171441; called by muse, mutect2, varscan2
- MTUS2 | c.977C>A p.A326E | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV70914107; called by muse, mutect2, varscan2
- MYT1 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs1333736281, COSV60510399, COSV60512728; called by muse, mutect2, varscan2
- NSUN2 | c.520G>T p.V174L | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV52955156; called by muse, mutect2, varscan2
- NTM | c.518C>A p.S173Y | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV66199916; called by muse, mutect2, varscan2
- OR2F2 | c.763A>G p.T255A | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs749379251; called by muse, mutect2, varscan2
- OR4A5 | c.557G>T p.C186F | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs762677617; called by muse, mutect2
- OR4S2 | c.382C>A p.L128I | Missense Mutation (SNP) | VAF 29/249 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV56747321; called by muse, mutect2, varscan2
- OR4S2 | c.560G>A p.C187Y | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56747612; called by muse, mutect2, varscan2
- OR5W2 | c.548C>A p.P183H | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100747757, COSV100747784; called by muse, mutect2, varscan2
- PAGE2 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 31/300 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV66595921; called by muse, mutect2, varscan2
- PCDHA3 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 160/1105 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.027); catalogued as rs782381789, COSV65366726; called by muse, mutect2, varscan2
- PDE1C | c.820G>T p.G274* | Nonsense Mutation (SNP) | VAF 43/373 reads (12%) | catalogued as COSV58503981, COSV58516090; called by muse, mutect2, varscan2
- PHKA2 | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 35/552 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV101177728; called by muse, mutect2
- PKN2 | c.2533G>C p.V845L | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV65143304; called by muse, mutect2, varscan2
- PRRT2 | c.992C>A p.S331Y | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.998); catalogued as COSV54882024; called by muse, mutect2, varscan2
- PXDN | c.2131C>T p.P711S | Missense Mutation (SNP) | VAF 90/831 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); catalogued as COSV99414781; called by muse, mutect2, varscan2
- RAB3GAP2 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 43/344 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52964436; called by muse, mutect2, varscan2
- RBP3 | c.2797C>A p.L933M | Missense Mutation (SNP) | VAF 73/539 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1454977555; called by muse, mutect2, varscan2
- SAMD9 | c.3862G>T p.E1288* | Nonsense Mutation (SNP) | VAF 54/618 reads (9%) | catalogued as rs1341453661; called by muse, mutect2
- SCN3A | c.5125G>T p.A1709S | Missense Mutation (SNP) | VAF 54/476 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV51807442; called by muse, mutect2, varscan2
- SHISA9 | c.991G>T p.D331Y | Missense Mutation (SNP) | VAF 36/270 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV69635820; called by muse, varscan2
- SLC22A6 | c.748C>A p.L250M | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100842863; called by muse, mutect2, varscan2
- SOS1 | c.2918A>T p.Q973L | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs727505016, COSV67675200; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPATA31D1 | c.3934G>A p.G1312R | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs748537115; called by muse, mutect2, varscan2
- ST8SIA3 | c.281G>T p.R94L | Missense Mutation (SNP) | VAF 72/404 reads (18%) | PolyPhen benign (0.019); catalogued as COSV60653438; called by muse, mutect2, varscan2
- SYT16 | c.1471C>T p.H491Y | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.08); catalogued as rs748021480, COSV70856218; called by muse, mutect2, varscan2
- TBCCD1 | c.1596G>A p.W532* | Nonsense Mutation (SNP) | VAF 37/237 reads (16%) | catalogued as rs764377776; called by muse, mutect2, varscan2
- TRPA1 | c.1202A>G p.Q401R | Missense Mutation (SNP) | VAF 61/519 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100084998; called by muse, mutect2, varscan2
- TRPC5 | c.1665del p.I556Sfs*28 | Frame Shift Del (DEL) | VAF 26/162 reads (16%) | catalogued as COSV53283263; called by mutect2, pindel
- TRPM7 | c.5536C>T p.L1846F | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.034); catalogued as rs1028964023; called by muse, mutect2
- UNC80 | c.233T>C p.V78A | Missense Mutation (SNP) | VAF 40/262 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV55901104; called by muse, mutect2, varscan2
- ZNF735 | c.896G>A p.C299Y | Missense Mutation (SNP) | VAF 17/258 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV70036271; called by muse, mutect2
- ZNF99 | c.1138A>C p.N380H | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.672); catalogued as rs879177593; called by muse, mutect2, varscan2
- ABCB11 | c.2731T>A p.L911M | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.971); called by muse, varscan2
- ABI3 | c.1091C>A p.P364H | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ABR | c.866G>T p.R289L (on ENST00000302538 / NM_021962.5; = p.R252L on NM_001092.5) | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ADCYAP1R1 | c.905G>T p.S302I | Missense Mutation (SNP) | VAF 44/327 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADGRB3 | c.3909G>T p.M1303I | Missense Mutation (SNP) | VAF 44/283 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADGRG4 | c.7650G>T p.M2550I | Missense Mutation (SNP) | VAF 48/320 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ANKEF1 | c.1437G>T p.Q479H | Missense Mutation (SNP) | VAF 31/359 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.012); called by muse, mutect2
- ANKEF1 | c.1438G>T p.D480Y | Missense Mutation (SNP) | VAF 33/363 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- ANKRD17 | c.6233A>G p.E2078G | Missense Mutation (SNP) | VAF 90/696 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ANKRD17 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- ANKRD30B | c.3581C>A p.T1194K | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- ANO4 | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 69/297 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- ANXA13 | c.827C>A p.A276D | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); called by muse, mutect2
- ARID2 | c.5192del p.K1731Rfs*4 | Frame Shift Del (DEL) | VAF 36/154 reads (23%) | called by mutect2, pindel, varscan2
- ARL6 | c.255-1G>C p.X85_splice | Splice Site (SNP) | VAF 37/264 reads (14%) | called by muse, mutect2, varscan2
- ARMCX5 | c.1515C>G p.F505L | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ASB1 | c.355G>C p.V119L | Missense Mutation (SNP) | VAF 74/617 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- BCO2 | c.548T>G p.V183G | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- C10orf90 | c.47G>A p.R16K | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2
- CACNA1G | c.5320C>A p.H1774N | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CATSPER1 | c.154C>T p.H52Y | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- CCDC166 | c.187G>T p.D63Y | Missense Mutation (SNP) | VAF 35/260 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- CCDC27 | c.527G>T p.R176M | Missense Mutation (SNP) | VAF 71/377 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- CDT1 | c.782del p.G261Afs*57 | Frame Shift Del (DEL) | VAF 39/352 reads (11%) | called by mutect2, pindel, varscan2
- CENPT | c.420del p.T141Qfs*17 | Frame Shift Del (DEL) | VAF 13/128 reads (10%) | called by mutect2, pindel
- CEP152 | c.3014A>G p.K1005R | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, varscan2
- CEP170 | c.1911G>T p.Q637H | Missense Mutation (SNP) | VAF 39/365 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLCN1 | c.1682T>A p.V561E | Missense Mutation (SNP) | VAF 48/377 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CMKLR1 | c.1042C>A p.P348T (on ENST00000312143 / NM_001142344.2; = p.P346T on NM_004072.3) | Missense Mutation (SNP) | VAF 58/235 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COX4I2 | c.498G>C p.K166N | Missense Mutation (SNP) | VAF 36/299 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- CRISP2 | c.638A>T p.N213I | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTCFL | c.1747A>G p.R583G | Missense Mutation (SNP) | VAF 29/270 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DAAM2 | c.922G>T p.G308C | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DLGAP4 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.063); called by muse, mutect2
- DMD | c.2221G>A p.V741M | Missense Mutation (SNP) | VAF 34/281 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAH7 | c.8822A>G p.D2941G | Missense Mutation (SNP) | VAF 30/252 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, varscan2
- DNER | c.641G>T p.R214L | Missense Mutation (SNP) | VAF 46/325 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- DNMT3B | c.1917G>T p.W639C | Missense Mutation (SNP) | VAF 54/414 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DOT1L | c.2937dup p.S980Vfs*59 | Frame Shift Ins (INS) | VAF 28/253 reads (11%) | called by mutect2, pindel, varscan2
- DPP6 | c.1322dup p.D442Gfs*54 (on ENST00000377770 / NM_001364500.2; = p.D380Gfs*54 on NM_001936.5) | Frame Shift Ins (INS) | VAF 19/180 reads (11%) | called by mutect2, pindel, varscan2
- EDEM2 | c.906G>T p.M302I | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- EFHC2 | c.999C>A p.Y333* | Nonsense Mutation (SNP) | VAF 18/294 reads (6%) | called by muse, mutect2
- EIF2AK3 | c.456G>T p.M152I | Missense Mutation (SNP) | VAF 49/363 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ELK1 | c.356T>C p.I119T | Missense Mutation (SNP) | VAF 46/474 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- EPHB6 | c.1918+6G>T | Splice Region (SNP) | VAF 61/507 reads (12%) | called by muse, mutect2, varscan2
- EPS8 | c.1332T>G p.F444L | Missense Mutation (SNP) | VAF 41/357 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM216B | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2
- FBN2 | c.8431C>A p.H2811N | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- FBXO21 | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- FLNA | c.4016C>G p.P1339R | Missense Mutation (SNP) | VAF 28/242 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- FLT3 | c.2633T>A p.L878Q | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FRMD4B | c.1775G>T p.S592I | Missense Mutation (SNP) | VAF 50/358 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- FRMD7 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- FSCN3 | c.1344G>T p.W448C | Missense Mutation (SNP) | VAF 27/259 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- GDF6 | c.1342G>T p.V448L | Missense Mutation (SNP) | VAF 23/249 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GHR | c.404C>G p.T135R | Missense Mutation (SNP) | VAF 53/391 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- GPC2 | c.412G>T p.A138S | Missense Mutation (SNP) | VAF 63/438 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- GRM8 | c.949C>A p.P317T | Missense Mutation (SNP) | VAF 35/305 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- HABP2 | c.919G>T p.A307S | Missense Mutation (SNP) | VAF 64/684 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- HCN4 | c.3368G>A p.G1123E | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2
- HCRTR2 | c.548T>A p.I183K | Missense Mutation (SNP) | VAF 63/485 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- HHIPL2 | c.321G>T p.Q107H | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HPGD | c.299G>T p.W100L | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- HRG | c.618C>A p.H206Q | Missense Mutation (SNP) | VAF 73/534 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HRNR | c.3138C>A p.H1046Q | Missense Mutation (SNP) | VAF 148/1238 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0); called by mutect2, varscan2
- IGKV1-9 | c.59C>G p.A20G | Missense Mutation (SNP) | VAF 44/344 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- IGKV3D-11 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 61/475 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- KCNH6 | c.1628A>T p.N543I | Missense Mutation (SNP) | VAF 72/505 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- KDM7A | c.1996G>T p.G666* | Nonsense Mutation (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- KIF1A | c.2835G>T p.E945D | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KRT2 | c.383del p.G128Afs*8 | Frame Shift Del (DEL) | VAF 44/208 reads (21%) | called by mutect2, pindel, varscan2
- KRT24 | c.218T>C p.V73A | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2
- LCNL1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- LGR6 | c.1392T>A p.S464R (on ENST00000367278 / NM_001017403.1; = p.S412R on NM_021636.3) | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- LIX1 | c.465G>T p.K155N | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- LRBA | c.7639del p.V2547* | Frame Shift Del (DEL) | VAF 31/223 reads (14%) | called by mutect2, pindel, varscan2
- LRRC4C | c.1103G>T p.G368V | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAGEB16 | c.836C>A p.P279Q | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MAPK7 | c.2311G>T p.A771S | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MED12 | c.3038C>G p.S1013* | Nonsense Mutation (SNP) | VAF 42/301 reads (14%) | called by muse, mutect2, varscan2
- MED13L | c.6268C>A p.L2090I | Missense Mutation (SNP) | VAF 69/312 reads (22%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MGAM2 | c.6166G>C p.A2056P | Missense Mutation (SNP) | VAF 47/439 reads (11%) | SIFT deleterious, low confidence (0.04); called by muse, mutect2, varscan2
- MMP10 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- MMP2 | c.528G>A p.W176* | Nonsense Mutation (SNP) | VAF 38/173 reads (22%) | called by muse, mutect2, varscan2
- MTM1 | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 35/290 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- MUC16 | c.15731C>A p.P5244Q | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYBPC2 | c.1018T>C p.F340L | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYO16 | c.911T>A p.L304Q | Missense Mutation (SNP) | VAF 35/291 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- N4BP2 | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- NHS | c.2405A>T p.D802V | Missense Mutation (SNP) | VAF 25/284 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2
- NLRP8 | c.3105C>A p.D1035E | Missense Mutation (SNP) | VAF 30/290 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2
- NOMO1 | c.1221-2A>T p.X407_splice | Splice Site (SNP) | VAF 26/149 reads (17%) | called by mutect2, varscan2
- NR0B1 | c.268dup p.T90Nfs*23 | Frame Shift Ins (INS) | VAF 30/337 reads (9%) | called by mutect2, pindel, varscan2
- NRK | c.1982C>A p.P661Q | Missense Mutation (SNP) | VAF 31/366 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.447); called by muse, mutect2
- OBSCN | c.7937C>T p.P2646L | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.106); called by muse, mutect2
- OBSCN | c.9433C>T p.H3145Y | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR2M7 | c.652T>C p.Y218H | Missense Mutation (SNP) | VAF 63/453 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR52R1 | c.555G>T p.M185I | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- OR5K3 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 30/246 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5T2 | c.613C>A p.L205I | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR6Q1 | c.742C>A p.H248N | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR8G1 | c.592C>A p.L198I | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- OTOG | c.7231G>T p.G2411C | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH15 | c.5372G>T p.*1791Lext*5 | Nonstop Mutation (SNP) | VAF 14/83 reads (17%) | called by muse, varscan2
- PCDH15 | c.755C>A p.T252K | Missense Mutation (SNP) | VAF 58/501 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHEX | c.920C>G p.A307G | Missense Mutation (SNP) | VAF 44/454 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.138); called by muse, mutect2
- PHKA2 | c.3501C>G p.I1167M | Missense Mutation (SNP) | VAF 68/802 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- PICALM | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- PLA2G4D | c.1279C>G p.L427V | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- PLAU | c.578T>G p.F193C | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- PLXNB3 | c.2849A>T p.Q950L | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- PNMA6A | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 74/1265 reads (6%) | called by muse, mutect2
- PNPLA5 | c.1121G>C p.W374S | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.023); called by muse, mutect2
- POLA1 | c.2147T>A p.L716Q | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRDM14 | c.133A>T p.T45S | Missense Mutation (SNP) | VAF 42/480 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2
- PRKDC | c.7607dup p.L2536Ffs*14 | Frame Shift Ins (INS) | VAF 32/282 reads (11%) | called by mutect2, varscan2
- PRRC2B | c.5808G>T p.Q1936H | Missense Mutation (SNP) | VAF 47/270 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PTPRZ1 | c.6528+1G>C p.X2176_splice | Splice Site (SNP) | VAF 17/99 reads (17%) | called by muse, mutect2
- RANBP2 | c.3169C>T p.P1057S | Missense Mutation (SNP) | VAF 32/245 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBFOX1 | c.317C>A p.S106Y | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- RGS22 | c.1581G>T p.W527C | Missense Mutation (SNP) | VAF 42/479 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RGS4 | c.593C>A p.A198D | Missense Mutation (SNP) | VAF 47/269 reads (17%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RIMS2 | c.842A>T p.E281V (on ENST00000666250 / NM_001348490.2; = p.E89V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.058); called by muse, mutect2
- RIMS2 | c.1551G>T p.E517D (on ENST00000666250 / NM_001348490.2; = p.E325D on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/281 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RP1 | c.4087G>A p.E1363K | Missense Mutation (SNP) | VAF 42/358 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RPAP1 | c.4121G>T p.R1374L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RSPO2 | c.617-2A>T p.X206_splice | Splice Site (SNP) | VAF 22/160 reads (14%) | called by muse, mutect2, varscan2
- RYR2 | c.4713C>A p.F1571L | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.057); called by muse, varscan2
- SCO1 | c.832G>T p.G278C | Missense Mutation (SNP) | VAF 88/624 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEZ6L | c.1709C>A p.P570H | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SH3TC2 | c.1849G>T p.A617S | Missense Mutation (SNP) | VAF 65/390 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SIGLEC1 | c.4981del p.A1661Pfs*66 | Frame Shift Del (DEL) | VAF 18/155 reads (12%) | called by mutect2, pindel, varscan2
- SLC10A3 | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC18A2 | c.122-2A>T p.X41_splice | Splice Site (SNP) | VAF 8/74 reads (11%) | called by muse, varscan2
- SLC3A2 | c.946A>G p.N316D | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- SLC5A7 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 45/327 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC9A2 | c.290G>A p.G97D | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLFN11 | c.2125C>T p.H709Y | Missense Mutation (SNP) | VAF 55/334 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SNAP91 | c.1079G>T p.G360V | Missense Mutation (SNP) | VAF 39/247 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- SPON1 | c.242C>A p.T81K | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- SQOR | c.548A>G p.Q183R | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.02); called by muse, mutect2
- SUCO | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2
- TAS2R4 | c.106G>T p.V36F | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- TBX22 | c.723G>T p.L241F | Missense Mutation (SNP) | VAF 59/485 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- TBX3 | c.681C>A p.H227Q | Missense Mutation (SNP) | VAF 63/316 reads (20%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TENM1 | c.1594T>A p.C532S | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- TENM1 | c.665C>A p.T222N | Missense Mutation (SNP) | VAF 18/209 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.629); called by muse, mutect2
- TENM4 | c.1119G>C p.Q373H | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TEP1 | c.6864G>T p.W2288C | Missense Mutation (SNP) | VAF 35/210 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- THSD7B | c.872A>T p.K291M | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); called by muse, varscan2
- TMLHE | c.922T>A p.C308S | Missense Mutation (SNP) | VAF 46/381 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TOGARAM2 | c.1962G>T p.M654I | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRAM1 | c.292C>G p.Q98E | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TRIML2 | c.73C>A p.P25T | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- TRPM2 | c.4429G>T p.V1477L | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- TTBK1 | c.2291A>G p.E764G | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- TUSC3 | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 52/429 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- UBQLN2 | c.1010G>C p.S337T | Missense Mutation (SNP) | VAF 66/890 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.019); called by muse, mutect2
- UNC5A | c.2046T>A p.N682K | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- VCAN | c.2318C>A p.T773N | Missense Mutation (SNP) | VAF 80/519 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- VIRMA | c.3755G>T p.G1252V | Missense Mutation (SNP) | VAF 34/273 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VIRMA | c.3754G>T p.G1252C | Missense Mutation (SNP) | VAF 35/272 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VNN1 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- WNK1 | c.4702C>T p.H1568Y (on ENST00000315939 / NM_018979.4; = p.H1321Y on NM_014823.3) | Missense Mutation (SNP) | VAF 34/248 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WNK4 | c.2402C>A p.S801Y | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- XPO4 | c.2492del p.L831* | Frame Shift Del (DEL) | VAF 23/219 reads (11%) | called by mutect2, pindel, varscan2
- ZNF182 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 9/89 reads (10%) | SIFT tolerated, low confidence (0.17); called by muse, mutect2, varscan2
- ZNF225 | c.460A>G p.K154E | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZNF423 | c.524A>T p.K175M (on ENST00000563137 / NM_001379286.1; = p.K167M on NM_015069.4) | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ZNF592 | c.3523G>C p.V1175L | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF679 | c.739A>G p.K247E | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- ZNF852 | c.1009A>T p.S337C | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- ARAF | c.147G>A p.L49= | Silent (SNP) | VAF 35/351 reads (10%) | called by muse, mutect2
- ARSF | c.1680G>C p.T560= | Silent (SNP) | VAF 26/256 reads (10%) | called by muse, mutect2
- BCORL1 | c.1044G>T p.A348= | Silent (SNP) | VAF 32/313 reads (10%) | called by muse, mutect2, varscan2
- BMP5 | c.906G>T p.V302= | Silent (SNP) | VAF 54/414 reads (13%) | called by muse, mutect2, varscan2
- C10orf71 | c.363A>T p.P121= | Silent (SNP) | VAF 11/113 reads (10%) | called by muse, mutect2
- CARS1 | c.153G>T p.T51= | Silent (SNP) | VAF 25/270 reads (9%) | called by muse, mutect2
- CCDC136 | c.1620G>C p.L540= | Silent (SNP) | VAF 26/204 reads (13%) | called by muse, varscan2
- CCDC168 | c.5448A>G p.E1816= | Silent (SNP) | VAF 26/204 reads (13%) | called by muse, mutect2, varscan2
- CFAP47 | c.183G>C p.P61= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV52890083; called by muse, mutect2
- CUX1 | c.4299G>C p.A1433= | Silent (SNP) | VAF 3/14 reads (21%) | called by muse, varscan2
- CXorf66 | c.537G>T p.L179= | Silent (SNP) | VAF 38/383 reads (10%) | called by muse, mutect2
- DAAM2 | c.921G>T p.L307= | Silent (SNP) | VAF 33/195 reads (17%) | called by muse, varscan2
- ELMO1 | c.564G>C p.V188= | Silent (SNP) | VAF 31/159 reads (19%) | called by muse, mutect2, varscan2
- ETNK2 | c.942G>A p.Q314= | Silent (SNP) | VAF 26/173 reads (15%) | catalogued as rs776441116; called by muse, mutect2, varscan2
- FREM2 | c.1920G>A p.V640= | Silent (SNP) | VAF 39/182 reads (21%) | called by muse, mutect2, varscan2
- FUNDC2 | c.477G>A p.R159= | Silent (SNP) | VAF 34/212 reads (16%) | catalogued as COSV101045374, COSV65671673; called by muse, mutect2, varscan2
- GFRA1 | c.1114C>A p.R372= | Silent (SNP) | VAF 32/213 reads (15%) | catalogued as rs147029195; called by muse, mutect2, varscan2
- GJA3 | c.177G>T p.P59= | Silent (SNP) | VAF 31/151 reads (21%) | catalogued as COSV53835086; called by muse, mutect2, varscan2
- GPR20 | c.522G>A p.V174= | Silent (SNP) | VAF 16/157 reads (10%) | catalogued as rs762498400; called by muse, mutect2, varscan2
- GREM2 | c.73C>A p.R25= | Silent (SNP) | VAF 20/143 reads (14%) | catalogued as rs1377063510, COSV100547888, COSV58956914; called by muse, mutect2, varscan2
- IPO8 | c.1914G>T p.R638= | Silent (SNP) | VAF 29/185 reads (16%) | called by muse, mutect2, varscan2
- ITGAX | c.1578A>G p.T526= | Silent (SNP) | VAF 18/141 reads (13%) | catalogued as rs773224320; called by muse, mutect2, varscan2
- KRT8 | c.351G>A p.K117= | Silent (SNP) | VAF 72/345 reads (21%) | called by muse, mutect2, varscan2
- MAGEB18 | c.255C>A p.A85= | Silent (SNP) | VAF 27/249 reads (11%) | called by muse, mutect2, varscan2
- MCMDC2 | c.1155G>A p.R385= | Silent (SNP) | VAF 21/268 reads (8%) | catalogued as COSV58038520; called by muse, mutect2
- MDGA2 | c.2202G>A p.V734= (on ENST00000399232 / NM_001113498.2; = p.V436= on NM_182830.4) | Silent (SNP) | VAF 16/126 reads (13%) | catalogued as COSV62083763; called by muse, mutect2, varscan2
- MIDN | c.1230G>C p.R410= | Silent (SNP) | VAF 35/320 reads (11%) | catalogued as COSV56294066; called by muse, mutect2, varscan2
- MMP17 | c.1734G>A p.V578= | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- MUC5AC | c.16593C>A p.T5531= | Silent (SNP) | VAF 67/620 reads (11%) | called by muse, mutect2, varscan2
- MYH9 | c.2124C>T p.F708= | Silent (SNP) | VAF 45/342 reads (13%) | catalogued as COSV99337603; called by muse, varscan2
- OR51I2 | c.804C>A p.V268= | Silent (SNP) | VAF 28/189 reads (15%) | called by muse, mutect2, varscan2
- PAPPA2 | c.2325C>A p.A775= | Silent (SNP) | VAF 31/136 reads (23%) | catalogued as COSV62780976; called by muse, mutect2, varscan2
- PCDH12 | c.3504G>A p.T1168= | Silent (SNP) | VAF 25/144 reads (17%) | catalogued as rs770633822; called by muse, mutect2, varscan2
- PCDHA6 | c.135G>T p.V45= | Silent (SNP) | VAF 53/389 reads (14%) | called by muse, mutect2, varscan2
- PGC | c.1078C>T p.L360= | Silent (SNP) | VAF 26/167 reads (16%) | catalogued as COSV57825050; called by muse, mutect2, varscan2
- PGK2 | c.795C>A p.I265= | Silent (SNP) | VAF 30/306 reads (10%) | catalogued as COSV59162610; called by muse, mutect2
- PLXNB3 | c.2850G>A p.Q950= | Silent (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2, varscan2
- PNMA5 | c.501C>A p.S167= | Silent (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2, varscan2
- PRKCI | c.1551G>A p.Q517= | Silent (SNP) | VAF 30/206 reads (15%) | called by muse, mutect2, varscan2
- PRSS1 | c.339C>T p.L113= | Silent (SNP) | VAF 60/469 reads (13%) | called by muse, mutect2, varscan2
- PURG | c.762A>G p.G254= | Silent (SNP) | VAF 60/352 reads (17%) | called by muse, mutect2, varscan2
- PXDN | c.2718C>G p.L906= | Silent (SNP) | VAF 31/255 reads (12%) | called by muse, mutect2, varscan2
- PYDC2 | c.87G>T p.L29= | Silent (SNP) | VAF 30/274 reads (11%) | catalogued as COSV72921233; called by muse, mutect2, varscan2
- RTL9 | c.3780C>A p.A1260= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as COSV71825415; called by muse, mutect2, varscan2
- RTTN | c.4068T>C p.S1356= | Silent (SNP) | VAF 21/221 reads (10%) | called by muse, mutect2
- RYR2 | c.5028G>T p.L1676= | Silent (SNP) | VAF 28/294 reads (10%) | called by muse, mutect2
- SHISA6 | c.891C>A p.P297= (on ENST00000409168 / NM_001173461.1; = p.P348= on NM_207386.4) | Silent (SNP) | VAF 22/136 reads (16%) | called by muse, mutect2, varscan2
- SORCS3 | c.861C>A p.T287= | Silent (SNP) | VAF 14/138 reads (10%) | catalogued as COSV63815663; called by muse, mutect2, varscan2
- SOX8 | c.765G>A p.G255= | Silent (SNP) | VAF 26/214 reads (12%) | catalogued as rs1169779271, COSV53510119; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.549C>T p.I183= | Silent (SNP) | VAF 53/257 reads (21%) | called by muse, mutect2, varscan2
- STRA6 | c.258C>A p.G86= | Silent (SNP) | VAF 37/304 reads (12%) | catalogued as rs779286611; called by muse, mutect2, varscan2
- TACC3 | c.2400G>A p.L800= | Silent (SNP) | VAF 37/304 reads (12%) | catalogued as COSV57602846; called by muse, mutect2, varscan2
- TCEA2 | c.864C>G p.V288= | Silent (SNP) | VAF 39/287 reads (14%) | called by muse, mutect2, varscan2
- TULP4 | c.3519T>C p.S1173= | Silent (SNP) | VAF 21/101 reads (21%) | called by muse, mutect2, varscan2
- VPS35 | c.2382C>T p.L794= | Silent (SNP) | VAF 38/332 reads (11%) | catalogued as rs776023975; called by muse, varscan2
- XYLT1 | c.2478C>T p.L826= | Silent (SNP) | VAF 18/171 reads (11%) | called by muse, mutect2
- ZIC3 | c.39G>T p.G13= | Silent (SNP) | VAF 28/204 reads (14%) | called by muse, varscan2
- ZNF71 | c.1107C>T p.L369= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as COSV100045963; called by muse, mutect2, varscan2
- ZSCAN26 | c.909C>T p.I303= (on ENST00000623276 / NM_001111039.2; = p.I169= on NM_152736.5) | Silent (SNP) | VAF 29/151 reads (19%) | catalogued as rs1474234581; called by muse, mutect2, varscan2
- AC107918.4 | n.1G>A | RNA (SNP) | VAF 9/33 reads (27%) | catalogued as rs1465388945; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73845517 G>T | 5'Flank (SNP) | VAF 29/167 reads (17%) | called by muse, mutect2, varscan2
- ATP11C | c.*23C>T | 3'UTR (SNP) | VAF 19/213 reads (9%) | called by muse, mutect2
- C22orf39 | c.*2620G>A | 3'UTR (SNP) | VAF 32/188 reads (17%) | called by muse, mutect2, varscan2
- CELF2 | c.53+12720G>A | Intron (SNP) | VAF 34/327 reads (10%) | catalogued as COSV64926799, COSV64931025; called by muse, mutect2, varscan2
- COL21A1 | c.2408-10T>A | Intron (SNP) | VAF 39/270 reads (14%) | called by muse, mutect2, varscan2
- EPB42 | c.10+16G>T | Intron (SNP) | VAF 46/348 reads (13%) | catalogued as COSV55751920; called by muse, mutect2, varscan2
- FAM90A20P | n.940C>A | RNA (SNP) | VAF 65/1115 reads (6%) | called by muse, mutect2
- FKBP10 | c.1063+206dup | Intron (INS) | VAF 5/46 reads (11%) | called by mutect2, pindel
- GABRG3 | c.270+11C>A | Intron (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2, varscan2
- GOLGA6L3 | n.579G>A | RNA (SNP) | VAF 22/214 reads (10%) | called by mutect2, varscan2
- GPATCH8 | c.*2142A>T | 3'UTR (SNP) | VAF 28/228 reads (12%) | called by muse, mutect2, varscan2
- GRIK2 | c.2563-4320C>A | Intron (SNP) | VAF 30/202 reads (15%) | called by muse, mutect2, varscan2
- HLA-L | n.785G>A | RNA (SNP) | VAF 35/179 reads (20%) | catalogued as rs746434070; called by muse, mutect2, varscan2
- KNG1 | c.-35C>A | 5'UTR (SNP) | VAF 58/376 reads (15%) | called by muse, mutect2, varscan2
- L1CAM | c.3457+24G>A | Intron (SNP) | VAF 62/420 reads (15%) | catalogued as rs377079563; called by muse, mutect2, varscan2
- LAMP2 | c.1093+2526G>A | Intron (SNP) | VAF 47/458 reads (10%) | catalogued as COSV52354492; called by muse, mutect2, varscan2
- LHX5 | c.*13del | 3'UTR (DEL) | VAF 10/84 reads (12%) | called by mutect2, pindel, varscan2
- LINC01036 | n.357C>A | RNA (SNP) | VAF 31/228 reads (14%) | called by muse, mutect2, varscan2
- MAP3K19 | c.-26A>G | 5'UTR (SNP) | VAF 24/219 reads (11%) | called by muse, varscan2
- MROH8 | c.-266C>T | 5'UTR (SNP) | VAF 24/117 reads (21%) | catalogued as rs779937321; called by muse, mutect2, varscan2
- NPL | c.*754T>A | 3'UTR (SNP) | VAF 21/246 reads (9%) | called by muse, mutect2
- OR2A13P | n.300C>A | RNA (SNP) | VAF 46/282 reads (16%) | called by muse, mutect2, varscan2
- PLA2G2F | c.-20G>A | 5'UTR (SNP) | VAF 30/190 reads (16%) | called by muse, mutect2, varscan2
- POR | c.*100G>A | 3'UTR (SNP) | VAF 83/638 reads (13%) | catalogued as rs782011186, COSV100115617; called by muse, mutect2, varscan2
- RGS21 | c.*22C>A | 3'UTR (SNP) | VAF 22/198 reads (11%) | called by mutect2, varscan2
- RPL7A | c.496-75G>A | Intron (SNP) | VAF 29/189 reads (15%) | catalogued as COSV100034673; called by muse, mutect2, varscan2
- SH2B1 | c.-96G>C | 5'UTR (SNP) | VAF 33/345 reads (10%) | called by muse, mutect2, varscan2
- SLC28A1 | c.461+349G>T | Intron (SNP) | VAF 24/343 reads (7%) | catalogued as COSV54483580; called by muse, mutect2
- SNORD116-29 | chr15:25106606 C>A | 3'Flank (SNP) | VAF 33/148 reads (22%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.622C>T | RNA (SNP) | VAF 55/356 reads (15%) | catalogued as rs532269947; called by muse, mutect2, varscan2
- SPATA8 | n.835G>T | RNA (SNP) | VAF 20/191 reads (10%) | catalogued as rs536286365, COSV60705341; called by muse, mutect2, varscan2
- TMX3 | c.311+86C>G | Intron (SNP) | VAF 22/131 reads (17%) | called by muse, mutect2, varscan2
- TWF1 | c.25+96G>C | Intron (SNP) | VAF 23/111 reads (21%) | called by muse, mutect2, varscan2
- Unknown | chr8:142982313 G>T | IGR (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2
- XIAP | c.*3318T>A | 3'UTR (SNP) | VAF 42/381 reads (11%) | called by muse, mutect2, varscan2
- XIST | n.9216C>A | RNA (SNP) | VAF 57/382 reads (15%) | catalogued as rs951773612; called by muse, mutect2, varscan2
- ZEB2 | c.73+5470T>A | Intron (SNP) | VAF 16/138 reads (12%) | called by muse, mutect2, varscan2
